Somatic mutation profile of tumor specimen TCGA-AA-3989-01A (aliquot TCGA-AA-3989-01A-01W-0995-10) from TCGA case TCGA-AA-3989, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 84.1 years (30,712 days).
Specimen TCGA-AA-3989-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a234011-a30b-45c9-baa8-c109927f4bc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3989-10A (Blood Derived Normal), aliquot TCGA-AA-3989-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc57ab75-448d-48d8-9625-b1044b419648

The open-access MAF lists 121 somatic variants for this specimen: 97 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 82, Silent 24, Nonsense Mutation 4, Frame Shift Del 4, Splice Region 2, Splice Site 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 58/173 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as rs786204688, CM032330, COSV61876871; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.8136dup p.D2713Rfs*10 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | catalogued as rs761483896; ClinVar: pathogenic; called by pindel, varscan2
- ACSS1 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100053616; called by muse, mutect2, varscan2
- ADAMTS12 | c.4177G>T p.D1393Y | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100710675, COSV100711757, COSV61279065; called by muse, mutect2
- ADAT2 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs866986087, COSV52795406; called by muse, mutect2, varscan2
- AGTR2 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 98/147 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs782035382, COSV64156715; called by muse, mutect2, varscan2
- AL031777.2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1216154213, COSV61911511; called by muse, mutect2, varscan2
- ANKRD11 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56365935; called by muse, mutect2, varscan2
- ANO5 | c.68A>T p.Y23F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100201725; called by muse, mutect2, varscan2
- ARFGEF3 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1164308106, COSV99293078; called by muse, mutect2
- ASH1L | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.138); catalogued as COSV64206359; called by muse, mutect2, varscan2
- C3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55569592; called by muse, mutect2, varscan2
- C4BPA | c.429A>G p.G143= | Splice Region (SNP) | VAF 15/90 reads (17%) | catalogued as rs972920982, COSV100891190; called by muse, mutect2, varscan2
- CAPZA3 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV56849599; called by muse, mutect2, varscan2
- CCDC60 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 128/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748181514, COSV59540707; called by muse, mutect2, varscan2
- CDH10 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1362800287, COSV100051622, COSV52575233, COSV52579534; called by muse, mutect2, varscan2
- CDH11 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV51756239; called by muse, mutect2, varscan2
- CDK12 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as COSV71000473, COSV71001049; called by muse, mutect2, varscan2
- CILP2 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910721427, COSV99364555; called by muse, mutect2
- COL4A1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.728); catalogued as rs569001394, COSV65423630; called by muse, mutect2, varscan2
- COL8A2 | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1356300718, COSV57440797; called by muse, mutect2, varscan2
- CSMD1 | c.3640G>T p.D1214Y (on ENST00000520002; = p.D1213Y on NM_033225.6) | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs954440887, COSV100146636, COSV59373696; called by muse, mutect2, varscan2
- CUBN | c.6758C>A p.A2253D | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100912455; called by muse, mutect2, varscan2
- DNAH11 | c.7786C>T p.R2596W | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs770163877, COSV100178624; called by muse, mutect2, varscan2
- DPP4 | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62111539; called by muse, mutect2, varscan2
- FCN1 | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV65662019; called by muse, mutect2, varscan2
- FERD3L | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs145174585, COSV51761804, COSV51763651; called by muse, mutect2, varscan2
- FGF12 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs766226672, COSV53167538; called by muse, mutect2, varscan2
- FLOT1 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as COSV99458145; called by muse, mutect2, varscan2
- FOLH1B | n.1770+1G>T | Splice Site (SNP) | VAF 23/87 reads (26%) | catalogued as rs775776779; called by muse, mutect2, varscan2
- FOXF2 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99453116; called by muse, mutect2
- FSIP2 | c.17971G>A p.A5991T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as rs769297860, COSV58097686; called by muse, mutect2, varscan2
- GABRG3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1471042419, COSV61514312, COSV61529275; called by muse, mutect2, varscan2
- GAD2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 175/439 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.303); catalogued as rs1259318388, COSV52150482; called by muse, mutect2, varscan2
- HECW1 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV101223275; called by muse, mutect2, varscan2
- HMCN1 | c.8777G>A p.R2926Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.993); catalogued as rs377760099; called by muse, mutect2, varscan2
- HOXD12 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101184221; called by muse, mutect2
- KAT6A | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55903305; called by muse, mutect2, varscan2
- KCNQ3 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.298); catalogued as rs143683496; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- KCNS1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100067183; called by muse, mutect2
- LAMA1 | c.4279G>A p.A1427T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV101055932; called by muse, mutect2, varscan2
- LIFR | c.2450G>A p.G817D | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54685333; called by muse, mutect2, varscan2
- LRRC49 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99537260; called by muse, mutect2, varscan2
- LRRC7 | c.328C>T p.R110* (on ENST00000651989 / NM_001370785.2; = p.R77* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/296 reads (7%) | catalogued as COSV50415481, COSV50652183; called by muse, mutect2
- LTBP1 | c.1070C>A p.T357N (on ENST00000404816 / NM_206943.4; = p.T31N on NM_000627.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100616850; called by muse, mutect2, varscan2
- MAP11 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs1554398694, COSV100385443; called by muse, mutect2, varscan2
- METTL3 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398168; called by muse, mutect2, varscan2
- MTR | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100855953; called by muse, mutect2, varscan2
- NEFL | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 90/448 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs1038686626, COSV55336349; called by muse, mutect2, varscan2
- NPAT | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99585940; called by muse, mutect2, varscan2
- OR51I1 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV66507307, COSV66507980; called by muse, mutect2, varscan2
- OR51I2 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 164/335 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as COSV100413374; called by muse, mutect2, varscan2
- OR56A1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs755147152, COSV57361805, COSV57362235; called by muse, mutect2, varscan2
- OTOGL | c.5203C>A p.H1735N (on ENST00000547103; = p.H1726N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54013747; called by muse, mutect2
- PAPPA2 | c.2928G>T p.E976D | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100867791; called by muse, mutect2, varscan2
- PCDH10 | c.3106C>T p.R1036W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as rs1424464634, COSV52090499; called by muse, mutect2, varscan2
- PCDH18 | c.1919C>A p.T640N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV61266371; called by muse, mutect2, varscan2
- PLCXD2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as rs147048469; called by muse, mutect2, varscan2
- PRDM2 | c.3244T>A p.S1082T | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV52455106, COSV99341385; called by muse, mutect2, varscan2
- PRKCH | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 146/662 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs754738854, COSV60646110; called by muse, mutect2, varscan2
- RBM45 | c.301-1G>C p.X101_splice | Splice Site (SNP) | VAF 25/82 reads (30%) | catalogued as COSV99617630; called by muse, mutect2, varscan2
- RIC1 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV99317107; called by muse, mutect2, varscan2
- ROBO1 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV71392072; called by muse, mutect2, varscan2
- SCN9A | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100312309; called by muse, mutect2, varscan2
- SIGLEC8 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs749472167, COSV58472107; called by muse, mutect2, varscan2
- SLC32A1 | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV54146516, COSV99462091; called by muse, mutect2, varscan2
- SMG5 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs1228224331, COSV62434597; called by muse, mutect2, varscan2
- SOX9 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55424739; called by muse, mutect2, varscan2
- SPTBN1 | c.5094C>A p.H1698Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100442336; called by muse, mutect2
- SYNE1 | c.23257C>T p.R7753C (on ENST00000367255 / NM_182961.4; = p.R7682C on NM_033071.3) | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138747167; called by muse, mutect2, varscan2
- SYT10 | c.866G>T p.R289I | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57345559, COSV99951211; called by muse, mutect2, varscan2
- SYT3 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 72/393 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs759062700, COSV58895639; called by muse, mutect2, varscan2
- TECTA | c.3748G>T p.D1250Y | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99879479; called by muse, mutect2, varscan2
- TEK | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV101193344; called by muse, mutect2, varscan2
- TEX2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs782624840, COSV51986665; called by muse, mutect2, varscan2
- TMEM108 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs761644701, COSV56590180; called by muse, mutect2
- TNFAIP6 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs564029423, COSV54640735; called by muse, mutect2, varscan2
- TRAPPC8 | c.3774A>T p.E1258D | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV51967808; called by muse, mutect2, varscan2
- TRIM69 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV57802964; called by muse, mutect2, varscan2
- TTLL7 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs371072730; called by muse, mutect2, varscan2
- UGT1A4 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59383308; called by muse, mutect2, varscan2
- UNC93A | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs772148244, COSV57811464; called by muse, mutect2, varscan2
- ZBTB33 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100434138; called by muse, mutect2
- ZNF135 | c.33G>A p.P11= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as rs749105473, COSV57880403; called by muse, mutect2, varscan2
- ZNF18 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100503072; called by muse, mutect2
- ZNF443 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV56890511; called by muse, mutect2, varscan2
- ZNF518A | c.4019G>A p.C1340Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs587756735; called by muse, mutect2, varscan2
- ZNF560 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV100038363, COSV56870672; called by muse, mutect2, varscan2
- ZNF713 | c.240A>C p.E80D (on ENST00000633730 / NM_001366796.2; = p.E93D on NM_182633.3) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV68887872; called by muse, mutect2, varscan2
- ZNF804B | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.142); catalogued as rs1396380791, COSV100303114; called by muse, mutect2, varscan2
- CEP170 | c.3573del p.V1192Yfs*26 | Frame Shift Del (DEL) | VAF 18/198 reads (9%) | called by mutect2, pindel
- CLIP1 | c.2973_2979del p.E992Lfs*32 (on ENST00000620786 / NM_001247997.1; = p.E981Lfs*32 on NM_002956.2) | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel
- STAU1 | c.88_89del p.Q30Afs*10 | Frame Shift Del (DEL) | VAF 34/353 reads (10%) | called by pindel, varscan2
- TCF20 | c.4162_4163del p.L1388Efs*6 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel, varscan2
- TFR2 | c.2109dup p.R704Tfs*88 | Frame Shift Ins (INS) | VAF 41/149 reads (28%) | called by mutect2, pindel, varscan2
- ARX | c.138C>A p.A46= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs144099565, COSV100984092, COSV66874849; called by muse, mutect2, varscan2
- CNGA1 | c.216A>T p.P72= | Silent (SNP) | VAF 50/214 reads (23%) | catalogued as COSV62053139; called by muse, mutect2, varscan2
- DNMBP | c.501G>A p.R167= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs1399389696, COSV60621221; called by muse, mutect2, varscan2
- DOCK9 | c.5877G>A p.A1959= (on ENST00000376460 / NM_001366676.2; = p.A1960= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs749137654, COSV59621337; called by muse, mutect2, varscan2
- GDF6 | c.489C>T p.G163= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV54623107; called by muse, mutect2
- GDNF | c.351T>A p.G117= | Silent (SNP) | VAF 59/300 reads (20%) | catalogued as COSV58478444; called by muse, mutect2, varscan2
- HOMER2 | c.33G>A p.A11= | Silent (SNP) | VAF 103/275 reads (37%) | catalogued as rs201522712, COSV58484566; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLRC1 | c.441T>C p.C147= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as COSV61724840; called by muse, varscan2
- KMT2D | c.10821G>A p.Q3607= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1228319716, COSV56415427; called by muse, mutect2, varscan2
- MFF | c.177C>T p.N59= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs775384816, COSV58825201; called by muse, mutect2, varscan2
- MYO7A | c.5718C>T p.V1906= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV68683674; called by muse, mutect2, varscan2
- MYO9A | c.7638T>C p.F2546= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV61848099; called by muse, mutect2, varscan2
- NEDD1 | c.354T>C p.H118= | Silent (SNP) | VAF 29/218 reads (13%) | catalogued as COSV57141792; called by muse, varscan2
- NHLRC2 | c.1347C>T p.L449= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs146402410; called by muse, mutect2, varscan2
- NOX3 | c.408G>A p.Q136= | Silent (SNP) | VAF 108/349 reads (31%) | catalogued as COSV99342990; called by muse, mutect2, varscan2
- NRXN1 | c.192C>T p.R64= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs748944452, COSV68004234; ClinVar: uncertain significance; called by muse, mutect2
- OLFML2A | c.339G>T p.A113= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs370096635, COSV100053768, COSV59160584; called by muse, mutect2, varscan2
- PARP8 | c.1530G>A p.V510= | Silent (SNP) | VAF 84/612 reads (14%) | catalogued as rs760414112, COSV55856519, COSV99889896; called by muse, mutect2, varscan2
- PTPRT | c.1128C>T p.P376= | Silent (SNP) | VAF 58/205 reads (28%) | catalogued as rs1315809674, COSV61963478; called by muse, mutect2, varscan2
- RASGRP3 | c.834C>A p.V278= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV67820649; called by muse, mutect2, varscan2
- SUOX | c.1275C>G p.V425= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV56266963; called by muse, mutect2, varscan2
- WDR46 | c.714G>A p.A238= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs748542598, COSV101004755; called by muse, mutect2, varscan2
- WSCD1 | c.453C>T p.D151= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs199602819, COSV58494104; called by muse, mutect2
- XKR6 | c.1341G>A p.T447= | Silent (SNP) | VAF 70/171 reads (41%) | catalogued as rs200587252, COSV58654171; called by muse, mutect2, varscan2
